TCGA case TCGA-VS-A9V0 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5885835-9473-455a-bac0-6fa43fa8a866

Demographics
Sex at birth: female; Country of residence at enrollment: Brazil; Age at index: 58 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 58.1 years (21,215 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 132 days; Days to treatment end: 169 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 144 days; Days to treatment end: 166 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 168 days; Days to treatment end: 186 days; Treatment dose: 2,800 cGy; Treatment outcome: Complete Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,800 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 4; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
2. Metastasis of diagnosis 1 (Mucinous adenocarcinoma, endocervical type), site: Intra-abdominal lymph nodes. Age at diagnosis: 59.4 years (21,690 days); Days to diagnosis: 475 days (1.3 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 475 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 475 days (1.3 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 529 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 551 days (1.5 years); ECOG performance status: 1.
- Days to follow up: 573 days (1.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 158 cm; BMI: 30.4.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 4.5; Tobacco smoking quit year: 2012; Age at onset: 27.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9V0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 140 mg.
  Slide TCGA-VS-A9V0-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-VS-A9V0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9V0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 7; Total pregnancy count: 7; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other).
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 4.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status other timing: Follow up; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 573 days; disease-specific survival: no event (censored), 573 days; disease-free interval: event (new tumor event after initially disease-free), 475 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 475 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9V0-01A-11D-A42N-01): tumor purity 0.78, ploidy 1.92, whole-genome doublings 0.
